Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5081, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5081-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT, LAPAROSCOPIC RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE III/IV, 5.5 CM IN GREATEST DIMENSION.
- B. DIRECT INVASION OF THE RENAL VEIN IS IDENTIFIED, GROSSLY AND MICROSCOPICALLY.
- C. TUMOR SHOWS NO EVIDENCE OF INVASION OF RENAL SINUS OR PERINEPHRIC ADIPOSE TISSUE (See comment).
- D. ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- E. URETERITIS CYSTICA IS PRESENT.
- F. ADRENAL GLAND IS NOT IDENTIFIED.
- G. PATHOLOGIC STAGE: pTNM = pT3b NX MX.

Source: NCI Genomic Data Commons file 6b4655b7-d766-4449-ac76-7be6185e2850 (TCGA-B0-5081.F33BAC8A-D76C-45E7-A7D5-AE93A45F8CF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).